Somatic mutation profile of tumor specimen TCGA-EL-A3T0-01A (aliquot TCGA-EL-A3T0-01A-22D-A22D-08) from TCGA case TCGA-EL-A3T0, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 46.0 years (16,798 days).
Specimen TCGA-EL-A3T0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a668b86-f658-4b05-89de-bf478b02f20b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3T0-11A (Solid Tissue Normal), aliquot TCGA-EL-A3T0-11A-12D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47cec569-cdaf-4044-a1d6-0854556ca4b1

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC180 | c.2066C>G p.S689C | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV63835733; called by muse, mutect2, varscan2
- IL12RB2 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs747423800, COSV52027477; called by muse, mutect2
- PTPRJ | c.1063G>C p.G355R | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69254767; called by muse, mutect2, varscan2
- TMTC4 | c.1625C>T p.A542V (on ENST00000376234 / NM_001350577.2; = p.A561V on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60893667; called by muse, mutect2
- ZNF335 | c.2764G>A p.G922S | Missense Mutation (SNP) | VAF 62/253 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV59820447; called by muse, mutect2, varscan2
- ZNF426 | c.505A>G p.S169G | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as COSV53470736; called by muse, mutect2
- ZNF791 | c.1571A>G p.Y524C | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58482925; called by muse, mutect2
- EIF2B5 | c.774C>T p.S258= (on ENST00000647909; = p.S250= on NM_003907.3) | Silent (SNP) | VAF 10/129 reads (8%) | catalogued as COSV56606336; called by muse, mutect2
- IMPG1 | c.183C>T p.F61= | Silent (SNP) | VAF 21/164 reads (13%) | catalogued as rs764226204, COSV64055878, COSV64057850; called by muse, mutect2, varscan2
- MAP7D2 | c.924G>A p.T308= | Silent (SNP) | VAF 46/345 reads (13%) | catalogued as rs992419109, COSV65528182; called by muse, mutect2, varscan2
